Somatic mutation profile of tumor specimen TARGET-40-PAVDSN-01A (aliquot TARGET-40-PAVDSN-01A-01D) from TARGET case TARGET-40-PAVDSN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Age at diagnosis: 13.6 years (4,954 days).
Specimen TARGET-40-PAVDSN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4d7c1f4-a95e-4c48-b077-133bf34acb5d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAVDSN-10A (Blood Derived Normal), aliquot TARGET-40-PAVDSN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c10834e-5d46-43b4-9d98-58ec84b48423

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 48/51 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs483352695, CM942294, COSV52664850, COSV52707693, COSV52949209, COSV53107767; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2608C>T p.H870Y | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV51765351; called by muse, mutect2, varscan2
- EYS | c.6244G>A p.V2082M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs1260770943, COSV65505710; called by muse, mutect2, varscan2
- OR4C11 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1390824261; called by muse, mutect2, varscan2
- TRHDE | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1435516049, COSV53831798; called by muse, mutect2, varscan2
- ROBO3 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENT4A | c.915A>T p.K305N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.333); called by muse, mutect2, varscan2
